Surgical pathology report (de-identified scan), TCGA case TCGA-15-1449, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Mayo Clinic - Rochester, specimen TCGA-15-1449-01A (Primary Tumor).

Final Diagnosis:

Brain, right frontal lobe-1,2,3, mass resection: [REDACTED] grade 4 (of 4) fibrillary astrocytoma (WHO grade IV, glioblastoma multiforme).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Preliminary Frozen Section Consultation:

High grade glioma. Hold for definitive diagnosis. [REDACTED]

Gross Description:

Tissue from the brain (right frontal--aggregating 1.8 x 1.0 x 0.3 cm; 5.8 x 2.8 x 2.0 cm, 4.8 x 3.2 x 1.2 cm)

Block Summary:

Part A: Right Frontal Brain

- 1 RT FRONTAL BRAIN
- 2 RT FRONTAL BRAIN

Part B: Right Frontal Brain #2

- 1 RT FRONTAL BRAIN #2
- 2 RT FRONTAL BRAIN #2
- 3 RT FRONTAL BRAIN #2

Source: NCI Genomic Data Commons file 49e41c86-012e-46e2-8ddf-96aff660a977 (TCGA-15-1449.66905C10-F988-40C5-8D0F-08AF3C6C499B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).